Somatic mutation profile of tumor specimen TARGET-40-NAAEDB-01A (aliquot TARGET-40-NAAEDB-01A-01D) from TARGET case TARGET-40-NAAEDB, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 28.5 years (10,427 days).
Specimen TARGET-40-NAAEDB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b529119-8780-4e91-abaa-350b48d52b34.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAEDB-10A (Blood Derived Normal), aliquot TARGET-40-NAAEDB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59530a53-1fff-4dc4-9e96-b299446bf470

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Nonsense Mutation 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL14A1 | c.2268C>A p.D756E | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.622); catalogued as rs767170417; called by muse, mutect2, varscan2
- PTPRF | c.4019A>G p.N1340S | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs754321401, COSV100740913; called by muse, mutect2, varscan2
- TMEM132B | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.155); catalogued as rs766246833; called by muse, mutect2, varscan2
- TP53 | c.657del p.Y220Mfs*27 | Frame Shift Del (DEL) | VAF 93/144 reads (65%) | catalogued as COSV52965002, COSV53107694, COSV53515706; called by mutect2, pindel, varscan2
- CMYA5 | c.5993G>T p.G1998V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- ECPAS | c.3314G>T p.R1105I | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MED12 | c.1230C>G p.N410K | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- RYR2 | c.8033C>T p.P2678L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TGM2 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- TTN | c.26766T>A p.Y8922* (on ENST00000591111; = p.Y7995* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 158/171 reads (92%) | called by muse, mutect2, varscan2
- ZNF143 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF469 | c.6716G>T p.R2239L (on ENST00000437464; = p.R2267L on NM_001367624.2) | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- DNAH9 | c.11895C>T p.A3965= | Silent (SNP) | VAF 20/131 reads (15%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.4842C>A p.I1614= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV67836110; called by muse, mutect2, varscan2
- ZFHX4 | c.7299G>A p.S2433= | Silent (SNP) | VAF 62/249 reads (25%) | catalogued as rs752991216, COSV99254802; called by muse, mutect2, varscan2
- EMG1 | c.412+14G>C | Intron (SNP) | VAF 20/120 reads (17%) | called by muse, varscan2
